Somatic mutation profile of tumor specimen 0DE7FM from CCDI case PBBPLT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,118 days).
Specimen 0DE7FM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0421f93b-be99-41d4-8f25-4c4312300da3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE7E4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/501ffac8-deac-4245-8d12-10f63d248db6

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USP53 | c.284C>A p.S95* | Nonsense Mutation (SNP) | VAF 348/1214 reads (29%) | catalogued as COSV99917448; called by muse, mutect2, varscan2
- TTN | c.71482G>A p.E23828K (on ENST00000591111; = p.E16404K on NM_003319.4) | Missense Mutation (SNP) | VAF 280/801 reads (35%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
